Gene-level copy-number profile of tumor specimen C3N-00179-03 from CPTAC case C3N-00179, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.5 years (25,370 days).
Specimen C3N-00179-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b0980e8a-49db-4807-8d65-cf5c8d80f360.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00179-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/6902dbd2-1df8-45d3-ab02-c4ab004e9a05

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 514; copy number 1: 934; copy number 2: 11,380; copy number 3: 16,234; copy number 4: 21,781; copy number 5: 4,631; copy number 6: 1,656; copy number 7: 269; copy number 8: 258; copy number 9: 1,031; copy number 10: 61; copy number 11: 29; copy number 13: 31; copy number 14: 3; copy number 16: 5; copy number 21: 19; copy number 25: 30; copy number 29: 4; copy number 31: 16; copy number 35: 8; copy number 36: 12.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:81,842,435–81,890,836, 2 genes (within-gene range 0–2): AP002802.2, MIR4300.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,249 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,606,334–149,747,818, 7 genes, copy number 11: LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P.
- chr1:183,186,238–183,418,380, 5 genes, copy number 16: LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1.
- chr8:71,155,454–143,976,734, 1,051 genes, copy number 9–13 (broad region; genes not listed).
- chr12:46,183,063–46,373,778, 4 genes, copy number 25–29: SLC38A1, AC025031.3, SLC38A2, AC025031.2.
- chr12:46,537,502–46,652,550, 2 genes, copy number 29 (within-gene range 3–29): AC008035.1, OR7A19P.
- chr12:57,693,955–60,341,941, 51 genes, copy number 14–35: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA.
- chr12:69,713,633–70,443,923, 12 genes, copy number 36: AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P.
- chr15:95,326,528–95,507,865, 2 genes, copy number 9 (within-gene range 7–9): LINC00924, AC027013.1.
- chr15:98,319,687–99,552,117, 28 genes, copy number 9: AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.4, RPL7P5.
- chr16:16,499,533–16,664,135, 1 gene, copy number 13 (within-gene range 5–13): AC136431.1.
- chr16:19,285,731–20,404,737, 27 genes, copy number 11–21 (within-gene range 3–21): CLEC19A, AC130456.1, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1, IQCK, AC027130.1, LARP7P2, GPRC5B, GPR139, AC092132.2, AC092132.1, SNRPEP3, GP2, UMOD, PDILT.
- chr16:20,409,534–20,489,659, 4 genes, copy number 25: ACSM5, AC137056.1, ACSM2A, AC137056.2.
- chr19:20,122,569–20,321,305, 1 gene, copy number 10 (within-gene range 3–10): AC011447.3.
- chr19:20,167,214–21,387,177, 54 genes, copy number 10: ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5, ZNF826P, BNIP3P20, AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23, ZNF737, AC010636.2, VN1R78P, AC010636.1, ZNF626, AC010329.5, AC010329.2, AC010329.1, VN1R79P, ZNF66, BNIP3P24, AC008739.2, ZNF85, AC008739.6, KRT18P40, AC008739.1, ZNF430, AC008739.3, VN1R80P, ZNF714, RNA5SP469, VN1R81P, ZNF431, RPL7AP10, VN1R82P, AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1.

Autosomal genes at a single copy (total copy number 1): 934. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
